Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3382, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3382-01A (Primary Tumor).

[page 1 of 2]
Collected Date & Time

TCGA-A3-3382

Result Name	Results	Units	Reference Range
☒ Surgical Pathology	COPY TO:		

COPY TO:

Pre-Op Diagnosis

Left renal mass

Post-Op Diagnosis

Nothing indicated

Clinical History

Nothing indicated

Gross Description:

Received in a single container labeled [REDACTED] - left kidney" is a previously bisected 1040 gram left nephrectomy specimen surrounded by a large amount of perinephric adipose tissue and faced anteriorly by a moderate amount of Gerota's fascia. The specimen on reconstruction measures 24.0 x 13.8 x 9.8 cm. The margins of resection include 1.5 cm of grossly patent renal artery, 1.3 cm of grossly patent renal vein and 7.0 cm of grossly patent ureter. The capsule strips with ease to reveal an organ measuring 12.4 x 8.5 x 6.9 cm on reconstruction. There is a lobulated slightly pale red-brown slightly granular cortex. The cortex measures up to 1.0 cm and is slightly granular red-brown. The corticomedullary junction is poorly defined. The medulla is red-brown with sharp papillae. The calyces and pelvis are lined by smooth gray-white mucosa extending into the ureter. Noted on the posterior aspect extending into the hilus is a well-defined 5.2 x 4.8 x 4.5 cm thinly encapsulated gray-tan to yellow nodule with a friable focally chalky, focally hemorrhagic gray-yellow to brown cut surface. The capsule appears grossly intact. This lesion grossly extends beyond the plane of the kidney into the surrounding adipose tissue; however, the capsule does not appear to be grossly transected. The lower pole calyx immediately adjacent to the lesion is dilated with a 0.6 x 0.5 x 0.4 cm granular brown-black calculus within the calyx. The lesion further appears to compress hilar adipose tissue and structures but does not grossly appear to extend into them. On further sectioning this parenchyma reveals a second slightly dilated lower pole calyx which has a 0.4 x 0.3 x 0.2 cm similar gray-brown to black calculus. Within the parenchyma adjacent to these dilated calyces there is a 0.4 x 0.4 x 0.4 cm well-defined unencapsulated tan-white fibrotic-appearing nodule. No additional gross lesions are identified. Within the specimen container are three tissue cassettes each labeled [REDACTED]. Representative sections are submitted labeled as follows: A - vascular and ureteral margin; B-H - lesion and surrounding tissue; I - random uninvolved parenchyma with dilated calyx and parenchymal nodule.

Microscopic Description:

[page 2 of 2]
Reviewed are slides labeled [REDACTED]

Final Diagnosis

Kidney, left, nephrectomy:

Tumor characteristics:

1. Histologic type: Renal cell carcinoma, conventional (clear cell) type
2. Tumor site: Posterior left kidney
3. Size: 5.2 x 4.8 x 4.5 cm
4. Macroscopic extent of tumor: Tumor limited to kidney
5. Nuclear grade: Fuhrman grade 3/4
6. Lymphovascular space invasion: Present
7. Transcapsular invasion: Not identified
8. Renal vein invasion: Not identified
9. Vena caval invasion: Not resected
10. Adrenal gland: Not resected

Surgical margin status:

1. Soft tissue margins: Negative for malignancy
2. Ureteral margin: Negative for malignancy
3. Vascular margins: Negative for malignancy

Lymph node status:

Not applicable (no lymph nodes resected with tumor specimen).

Other significant findings:

1. 0.4 cm renal calculus.
2. Microscopic healed renal infarct

Stage:

pT1b Nx Mx PAS 9 SPC-NG

CPT: 88309

Comment

This case has been reviewed by Dr [REDACTED] who concurs with the diagnosis.

This test has been finalized at the [REDACTED]

Electronically Signed by: # [REDACTED]

Source: NCI Genomic Data Commons file dbb8026f-e10c-4ef5-ace8-8c25317b8757 (TCGA-A3-3382.7302603F-EF54-4F7B-85EC-D6B06AE79D54.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).